Surgical pathology report (de-identified scan), TCGA case TCGA-B7-A5TN, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Cureline, specimen TCGA-B7-A5TN-01A (Primary Tumor).

Index	Specimen label	Clinical Site #	Case #	DOB (mm/dd/yyyy)	Sex	Ethnicity (Race)	Clinical Diagnosis	Date of procurement	Anatomical Site	Tumor Location	Tissue Specification	Specimen Matrix	Specimen Format	Container	Number of containers	Amount/type of container	Unit	Type of Procurement	Histological description	Grade	TNM Stage (T)	TNM Stage (N)	TNM Stage (M)	Treatment type	Component of treatment (Chemo / Horm Th Details)	Tumor cell %
					male	Caucasian (White)	Gastric cancer		Stomach, fundus	Primary	Tumor	Tissue	OCT	block	1	200	mg	surgery	Stomach intestinal Adenocarcinoma	3	4	3	0	none	n/a	40
					male	Caucasian (White)	Gastric cancer		Blood	n/a	Normal	Blood	frozen	tube	1	4	ml	blood draw	n/a	n/a	n/a	n/a	n/a	none	n/a	n/a

ICD-0-3
Adenocarcinoma, intestinal
type 8144/3
Site: Gastric fundus C16.1
JW 4/29/13

Source: NCI Genomic Data Commons file 7fa3472a-0587-451b-b886-dad7cacad2e4 (TCGA-B7-A5TN.936A76BC-9144-442A-868C-DC9E19E10645.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).